Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A1QG, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A1QG-01A (Primary Tumor).

[page 1 of 3]
Dr 3/14/11

Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type:
Additional Copy to:

Clinical Diagnosis & History:

Bilateral thyroid nodularity with atypical fine needle aspiration biopsy involving the left lobe of thyroid.

Specimens Submitted:

- 1: SP: Pretracheal tissue (fs)
- 2: THYROID; TOTAL THYROIDECTOMY

DIAGNOSIS:

1. LYMPH NODE, PRETRACHEAL; BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).

100-0-3

Carcinoma, papillary and follicular 8340/3

Site: thyroid NOS C73.9 3/10/11

2. THYROID; TOTAL THYROIDECTOMY:

Tumor Type:

Four foci of papillary carcinoma: one classical type, one follicular variant and two microcarcinomas

Histologic Grade:

Well differentiated

Mitotic Activity:

Mild to moderate
1/10 HPFs

Tumor Necrosis:

Not identified

Other Tumor Features:

Calcification of non-psammoma type

Tumor Location:

Both lobes

Tumor Size:

4 tumors with greatest diameters of 1.8 (right lobe), 1.1 (right lobe), 0.5 (right lobe), and 0.1 cm (left lobe)

Tumor Encapsulation:

Completely surrounded
For the two largest tumor foci

Capsular Invasion:

For the largest tumor focus

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

Not identified

[page 2 of 3]
Surgical Margins:
Free of tumor

Tumor Multicentricity:
Gross foci present

Non-Neoplastic Thyroid:
No abnormalities identified

Parathyroid Glands:
Not identified

Lymph Nodes:
Four benign lymph nodes (0/4)

Comment: The largest tumor focus (classical type) shows focal areas of solid growth pattern.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1) Specimen received fresh, labeled "pretracheal tissue" and consists of tan-pink tissue fragment measuring 0.6x0.4x0.2 cm. Entirely submitted for frozen section diagnosis.

Summary of sections:
FSC- frozen section control

2. The specimen is received fresh, labeled "total thyroid" and consists of a thyroid weighing 27.5 g. The right lobe measures 6.2 x 2x 2 cm, the left lobe measures 5.5x 2.2 x 2.1 cm and the isthmus measures 1.5 x 1 x 0.5 cm. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked purple. Sectioning reveals a homogeneous tan nodule (1.8 x 1.5 x 1.5 cm) located in the left lobe. There is a second nodule 1.1 cm in diameter located adjacent to the first nodule. The right lower lobe has a 2 x 1.5 cm nodule with a heterogeneous tan and white cut surface. Sections through the remaining tissue reveal red-brown unremarkable cut surface. The remaining thyroid parenchyma is red tan and beefy. Representative sections of the specimen are submitted for TPS. The remaining tissue is serially sectioned and entirely submitted.

Summary of sections:
N - nodule
N2 - second nodule
NR - right nodule
RL - right lobe
LL - left lobe

Summary of Sections:

Part 1: SP: Pretracheal tissue (fs)

Block	Sect. Site	PCs
1	fsc	1

Part 2: THYROID; TOTAL THYROIDECTOMY

Block	Sect. Site	PCs
-------	------------	-----

[page 3 of 3]
1	IS	2
3	LL	5
3	N	3
1	N2	1
3	NR	3
4	RL	5

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. FROZEN SECTION DIAGNOSIS: SP: PRETRACHEAL TISSUE (FS): LYMPH NODE WITH NO CARCINOMA SEEN.
[REDACTED]
PERMANENT DIAGNOSIS: SAME

Source: NCI Genomic Data Commons file 975b2833-ab92-4820-827b-cc4acda43028 (TCGA-DJ-A1QG.EEEC9799-0C51-4221-87CE-9C9AA24B0742.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).